Gene-level copy-number profile of tumor specimen TCGA-R6-A6KZ-01A from TCGA case TCGA-R6-A6KZ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G3; Age at diagnosis: 42.5 years (15,512 days).
Specimen TCGA-R6-A6KZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.ab422d43-1b4a-4edd-b28c-cb2ed1dd96ee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R6-A6KZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/67ac6de5-9b64-442d-ba09-c834b01d0047

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 15; copy number 2: 1,768; copy number 3: 1,472; copy number 4: 27,020; copy number 5: 5,983; copy number 6: 14,167; copy number 7: 3,285; copy number 8: 4,384; copy number 9: 932; copy number 10: 739; copy number 12: 15; copy number 13: 34.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-R6-A6KZ-01A-11D-A31T-01): tumor purity 0.47, ploidy 2.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr14:27,612,577–27,639,636, 2 genes: LINC00645, MIR3171.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,720 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:97,796,921–99,309,590, 15 genes, copy number 12: DPYD-AS2, AC114878.2, MIR137HG, BX005019.1, MIR2682, MIR137, AC104453.1, NFU1P2, LINC01776, AC095031.1, SNX7, PLPPR5, AL445433.2, AL445433.1, PLPPR4.
- chr1:143,343,180–152,115,454, 357 genes, copy number 10 (broad region; genes not listed).
- chr1:228,006,998–232,832,187, 142 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr1:243,917,402–248,919,946, 171 genes, copy number 10 (broad region; genes not listed).
- chr4:1,683,420–1,856,156, 7 genes, copy number 9: Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1.
- chr5:162,424,042–165,241,756, 23 genes, copy number 9: AC113414.1, RNU6-164P, ARL2BPP5, MRPL57P6, AC008723.1, CCNG1, NUDCD2, HMMR, HMMR-AS1, MAT2B, AC010291.1, AC116917.1, RNU6-168P, AC008432.1, LSM1P2, AC008662.1, AC008662.2, AC109466.1, LINC02143, AC008446.1, RNU6-209P, AC091973.1, LINC01938.
- chr7:7,102,573–62,275,678, 902 genes, copy number 9 (broad region; genes not listed).
- chr16:14,974,591–15,139,339, 1 gene, copy number 13 (within-gene range 8–13): PDXDC1.
- chr16:15,037,854–18,937,043, 102 genes, copy number 10–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
